Surgical pathology report (de-identified scan), TCGA case TCGA-BB-7863, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-7863-01A (Primary Tumor).

[page 1 of 7]
[REDACTED]

INTERPRETATION AND DIAGNOSIS: [REDACTED]

1. POSTERIOR DORSUM (EXCISION): NEGATIVE FOR TUMOR.
2. ANTERIOR DORSUM (EXCISION): NEGATIVE FOR TUMOR.
3. ANTERIOR VENTRAL TONGUE (EXCISION): NEGATIVE FOR TUMOR.
4. ANTERIOR DEEP TONGUE (EXCISION): NEGATIVE FOR TUMOR.
5. POSTERIOR MARGIN (EXCISION): NEGATIVE FOR TUMOR.
6. POSTERIOR DEEP (EXCISION): NEGATIVE FOR TUMOR.
7. POSTERIOR VENTRAL TONGUE (EXCISION): NEGATIVE FOR TUMOR.
8. RE-RESECTION ANTERIOR DEEP TONGUE (EXCISION): NEGATIVE FOR TUMOR.
9. LEFT PARTIAL GLOSSECTOMY:

SPECIMEN TYPE:

Left partial glossectomy

TUMOR SITE:

Oral cavity - oral tongue

TUMOR SIZE:

Greatest dimension: 5.0 cm. The greatest depth of invasion is 1.0 cm

HISTOLOGIC TYPE:

Squamous cell carcinoma, conventional

HISTOLOGIC GRADE:

G2: Moderately differentiated

EXTENT OF INVASION [REDACTED] AJCC):

PRIMARY TUMOR (pT):

ORAL TONGUE pT3: Tumor more than 4 cm in greatest dimension

REGIONAL LYMPH NODES (pN):

pN0: No regional lymph node metastasis

Number examined: 16

MARGINS:

Margins uninvolved by tumor

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:

Absent

[REDACTED]

FINAL DOCUMENT

[REDACTED]

[page 2 of 7]
PERINEURAL INVASION:
none identified

10. LEFT NECK LEVEL 1 (DISSECTION): THREE BENIGN LYMPH NODES.

11. ANTERIOR TONGUE (RESECTION): NEGATIVE FOR TUMOR.

12. LEVELS II-IV, LEFT NECK (DISSECTION):

LEVEL II: NINE BENIGN LYMPH NODES.

LEVEL III; TWO BENIGN LYMPH NODES.

LEVEL IV: TWO BENIGN LYMPH NODES.

[REDACTED]

*Electronic signature by which I attest that the above diagnosis is based upon my personal examination of the slides (and / or other material indicated in the diagnosis), and that I have reviewed and approved this report.

=====

Clinical History:

LEFT PARTIAL GLOSSECTOMY

GROSS DESCRIPTION

PART #1: FS: POSTERIOR DORSUM [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Posterior Dorsum: Negative for tumor.

Dictated by: [REDACTED]

The specimen is received in twelve (12) parts.

The specimen for Part 1 is received fresh for frozen section, labeled with the patient's name [REDACTED] and designated 'Posterior Dorsum.' The specimen consists of five (5) fragments of pink-tan soft tissue measuring 1.0 x 1.0 x 0.2 cm, in aggregate. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS:

1 - FSC - 5 (FROZEN SECTION CONTROL, POSTERIOR DORSUM)
1 - TOTAL - 5

PART #2: FS: ANTERIOR DORSUM [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Anterior Dorsum: Negative for tumor.

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 3 of 7]
Dictated by: [REDACTED]

The specimen for Part 2 is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Anterior Dorsum.' The specimen consists of one (1) piece of pink-tan soft tissue measuring 1.5 x 0.5 x 0.2 cm. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS:

1 - FSC - 1 (FROZEN SECTION CONTROL, ANTERIOR DORSUM)
1 - TOTAL - 1

PART #3: FS: ANTERIOR VENTRAL TONGUE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Anterior Ventral Tongue: Negative for tumor.

Dictated by: [REDACTED]

The specimen for Part 3 is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Anterior Ventral Tongue.' The specimen consists of one (1) fragment of pink-tan soft tissue measuring 2.0 x 0.4 x 0.3 cm. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS:

1 - FSC - 1 (FROZEN SECTION CONTROL, ANTERIOR VENTRAL TONGUE)
1 - TOTAL - 1

PART #4: FS: ANTERIOR DEEP TONGUE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Anterior Deep Tongue: Detached fragment of atypical squamous epithelium; as discussed.

Dictated by: [REDACTED]

The specimen for Part 4 is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Anterior Deep Tongue.' The specimen consists of two (2) irregular fragments of red-pink soft tissue each measuring approximately 0.5 cm. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS:

1 - FSC - 2 (FROZEN SECTION CONTROL, ANTERIOR DEEP TONGUE)
1 - TOTAL - 2

PART #5: FS: POSTERIOR MARGIN [REDACTED]

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 4 of 7]
Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Posterior Margin: Negative for tumor.

The specimen for Part 5 is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Posterior Margin.' The specimen consists of a 1.0 x 0.4 x 0.4 cm unoriented fragment of red-pink soft tissue. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS:

1 - FSC - 1 (FROZEN SECTION CONTROL, POSTERIOR MARGIN)

1 - TOTAL - 1

PART #6: FS: POSTERIOR DEEP [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Posterior Deep: Negative for tumor.

Dictated by: [REDACTED]

The specimen for Part 6 is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Posterior Deep.' The specimen consists of a 1.0 x 0.5 x 0.4 cm irregular unoriented fragment of red-pink soft tissue. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS:

1 - FSC - 1 (FROZEN SECTION CONTROL, POSTERIOR DEEP)

1 - TOTAL - 1

PART #7: FS: POSTERIOR VENTRAL TONGUE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Posterior Ventral Tongue: Negative for tumor.

Dictated by: [REDACTED]

The specimen for Part 7 is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'Posterior Ventral Tongue.' The specimen consists of a 1.5 x 0.5 unoriented fragment of red soft tissue. The specimen is submitted in its entirety for frozen section diagnosis.

SUMMARY OF SECTIONS:

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 5 of 7]
1 - FSC - 1 (FROZEN SECTION CONTROL, POSTERIOR VENTRAL TONGUE)
1 - TOTAL - 1

PART #8: FS: RE RESECTION ANTERIOR DEEP TONGUE

Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists:

FS: Re-Resection Anterior Deep Tongue: Negative for tumor.

Dictated by:

The specimen for Part 8 is received fresh for frozen section, labeled with the patient's name, and designated 'Re-Resection Anterior Deep Tongue.' The specimen consists of a single red-tan portion of soft tissue measuring 0.6 x 0.5 x 0.3 cm. The specimen is submitted in its entirety for frozen section diagnosis, in tissue paper.

SUMMARY OF SECTIONS:

1 - FSC - 1 (FROZEN SECTION CONTROL, RE-RESECTION ANTERIOR DEEP TONGUE)

1 - TOTAL - 1

PART #9: LEFT PARTIAL GLOSSECTOMY

Resident Pathologist:

Dictated by:

The specimen for Part 9 is received fresh, labeled with the patient's name, and designated 'Left Partial Glossectomy.' The specimen consists of a partial glossectomy specimen which has been oriented as such: Long Stitch-Anterior Margin; Short Stitch-Medial Margin. The specimen itself measures 5.5 x 3.0 x 1.5 cm. The deep margin is cauterized, and the superficial surface of the specimen contains a fleshy raised area of tumor measuring 5.0 x 2.5 x 0.8 cm. Of note, the fleshy tumor bulges out superficially. The specimen is inked as follows: anterior-medial margin edge-red, posterior-medial margin edge-green, posterior-lateral margin edge-orange, and anterior-lateral margin edge-blue. The rest of the deep margin is inked black. The specimen is serially sectioned to reveal a relatively well-defined white tumor cut surface which appears to respect the red tongue parenchyma at the posterior end of the specimen. The white area becomes more diffuse and grossly appears to extend more closely to the deep margin at the anterior end of the specimen. Grossly, the tumor appears to come no closer than 3.0 mm of the deep margin. Representative sections are submitted, more sections from the anterior end of the specimen. A representative photograph is taken prior to sectioning the specimen and sections are marked on the photograph. Approximately fifty percent (50%) of the specimen is submitted, including the posterior and anterior ends of the specimen in representative sections from the middle of the specimen.

SUMMARY OF SECTIONS:

1 - A - 1 (POSTERIOR END)

1 - B - 1 (ANTERIOR END)

5 - C-G - 1 EA (POSTERIOR TO ANTERIOR, REPRESENTATIVE SECTIONS AS

FINAL DOCUMENT

[page 6 of 7]
MARKED ON PHOTOGRAPH)

7 - TOTAL - 7

PART #10: LEFT NECK LEVEL 1 [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh and labeled with the patient's name [REDACTED] and is designated left neck level 1. The specimen consists of red yellow soft tissue attached to a tan red salivary gland measuring 7 x 2.5 x 2.0 cm in total. The spat is dissected to reveal three possible lymph nodes ranging in size from 0.3 to 1.2 cm. The nodes and surrounding soft tissue are submitted in their entirety. The salivary gland is sectioned to reveal homogeneous tan yellow cut surface. A representative section of the salivary gland is also submitted.

SUMMARY OF SECTIONS:

- 2 - A - B - 2/EACH (ONE BISECTED LYMPH NODE EACH)
- 1 - C - 2 (ONE LYMPH NODE WITH SOFT TISSUE)
- 1 - D - 1 (REPRESENTATIVE GLAND)
- 4 - TOTAL - 7

PART #11: ANTERIOR TONGUE RESECTION [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh and labeled with the patient's name [REDACTED] and designated anterior tongue re-resection. The specimen consists of a single fragment of red tan tissue measuring 2 x 1 x 0.3 cm. The specimen is not oriented. The specimen is sectioned to reveal no gross masses or lesions and submitted in its entirety.

SUMMARY OF SECTIONS:

- 1 - A - 3
- 1 - TOTAL - 3

PART #12: LEVELS II-IV LEFT NECK DISSECTION [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh and labeled with the patient's name [REDACTED] and designated neck dissection levels II-IV. The specimen consists of red soft tissue measuring 5 x 2 x 1 cm. The specimen is oriented such that levels II - IV are designated with staples. There is also an additional unattached lymph node which measures 1.9 cm in maximum dimension. The levels are dissected individually and lymph nodes are found as follows: level II - four possible lymph nodes ranging in maximum dimension from 0.3 to 0.9 cm, level III four possible lymph nodes ranging in size from 0.3 to 0.4 cm, and level IV two possible lymph nodes ranging in maximum dimension from 0.3 to 1.3 cm. All lymph nodes are submitted as well as all attached soft tissue. therefore, the specimen is submitted in its entirety.

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 7 of 7]
SUMMARY OF SECTIONS:

1 - A - 2 (ONE BISECTED UNATTACHED LYMPH NODE)
1 - B - 4 (FOUR POSSIBLE LYMPH NODES FROM LEVEL II)
1 - C - 4 (REMAINING SOFT TISSUE FROM LEVEL II)
1 - D - 4 (FOUR POSSIBLE LYMPH NODES FROM LEVEL III)
1 - E - 4 (REMAINING SOFT TISSUE FROM LEVEL III)
1 - F - 2 (ONE BISECTED LYMPH NODE FROM LEVEL IV)
1 - G - 1 (ONE POSSIBLE LYMPH NODE FROM LEVEL IV)
1 - H - 1 (REMAINING SOFT TISSUE FROM LEVEL IV)
1 - I - 1 (REMAINING SOFT TISSUE FROM LEVEL IV)
9 - TOTAL - 22

Other Surgical Pathology Specimens known to the computer: [REDACTED]

=====

(End of Report) [REDACTED]

Note: This note provides information pertaining only to a specific event. A more detailed medical history is available in the Medical Record.

[REDACTED] FINAL DOCUMENT [REDACTED]

Source: NCI Genomic Data Commons file dcb56e50-f6ab-432e-8e69-43549ed4f559 (TCGA-BB-7863.D4AD7DD0-184F-44AF-9B0A-6CB1DFCC1AFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).